Somatic mutation profile of tumor specimen BA2315D (aliquot aq-BA2315D) from BEATAML1.0 case 2396, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.4 years (19,496 days).
Specimen BA2315D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 085fd22e-82a9-4d2a-a4e0-59ec3db5630c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2231D (Solid Tissue Normal), aliquot aq-BA2231D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80b666e7-79d0-49c8-b0ee-d144a3f6f7e3

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, Intron 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MC1R | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs774680166, COSV59626514; called by muse, mutect2, varscan2
- NPM1 | c.863_864insTTCG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 32/93 reads (34%) | catalogued as COSV51544444, COSV51555499, COSV51560925, COSV51570713; called by mutect2, pindel, varscan2
- MEGF8 | c.2187G>T p.M729I | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MNT | c.31C>A p.R11S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by muse, varscan2
- PLCB2 | c.3157G>T p.E1053* | Nonsense Mutation (SNP) | VAF 104/235 reads (44%) | called by muse, mutect2, varscan2
- RANBP3 | c.916A>G p.S306G (on ENST00000340578 / NM_007322.3; = p.S301G on NM_003624.3) | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SEC16B | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM129 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2
- CNTNAP3 | c.3654C>T p.P1218= | Silent (SNP) | VAF 18/66 reads (27%) | called by mutect2, varscan2
- KRT5 | c.948G>A p.T316= | Silent (SNP) | VAF 248/548 reads (45%) | catalogued as rs191863441; called by muse, mutect2, varscan2
- SGSM2 | c.405G>A p.A135= | Silent (SNP) | VAF 40/78 reads (51%) | catalogued as rs564304044, COSV52158486; called by muse, mutect2, varscan2
- TEKT4 | c.516G>A p.R172= | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as rs782640153; called by muse, mutect2, varscan2
- ZBTB1 | c.99T>C p.I33= | Silent (SNP) | VAF 79/168 reads (47%) | catalogued as rs969268091; called by muse, mutect2, varscan2
- CES2 | c.76+76C>A | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- EIF4A1 | c.996+82G>C | Intron (SNP) | VAF 96/245 reads (39%) | called by muse, mutect2, varscan2
